Somatic mutation profile of tumor specimen C3N-02944-01 (aliquot CPT0208690013) from CPTAC case C3N-02944, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 62.0 years (22,648 days).
Specimen C3N-02944-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef46c087-b5c8-4db6-b95c-366fdf47e1db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02944-31 (Blood Derived Normal), aliquot CPT0208750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f29d2328-4016-4c2c-8d12-52f9cb7075d6

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Intron 1, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/274 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2
- AICDA | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 29/341 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57563615; called by muse, mutect2
- KCNA5 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs898525645, COSV52905174; ClinVar: uncertain significance; called by muse, mutect2
- LCT | c.2407G>C p.D803H | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51556202; called by muse, mutect2
- NLRP8 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | catalogued as COSV52586071; called by muse, varscan2
- PPEF2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54422600; called by muse, mutect2, varscan2
- PPFIA3 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1184428081, COSV61949585; called by muse, mutect2
- PPP1R26 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs756198560, COSV100778066; called by muse, mutect2
- PRPF6 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369787039, CM153031; ClinVar: uncertain significance; called by muse, mutect2
- PWWP2B | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs200265938; called by muse, mutect2
- ZNF335 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs768453184, COSV100532841; called by muse, mutect2
- ZNF536 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV62828022; called by muse, mutect2
- ATP1A1 | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 29/405 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2
- CLEC17A | c.1028A>G p.N343S (on ENST00000417570 / NM_001204118.2; = p.Q306= on NM_207390.3) | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYLD | c.1675A>G p.N559D | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- DIPK2A | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2
- ETHE1 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.275); called by muse, mutect2
- LRP2 | c.8915G>C p.C2972S | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA6A | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.486); called by muse, mutect2
- SLC4A10 | c.1564T>C p.S522P (on ENST00000446997 / NM_001354461.2; = p.S492P on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ANK3 | c.10275T>C p.D3425= | Silent (SNP) | VAF 10/159 reads (6%) | catalogued as rs1246826313; called by muse, mutect2
- LRP4 | c.4362G>A p.A1454= | Silent (SNP) | VAF 35/677 reads (5%) | catalogued as rs775166531; called by muse, mutect2
- PCDHA3 | c.1566G>A p.P522= | Silent (SNP) | VAF 60/948 reads (6%) | catalogued as rs146921578; called by muse, mutect2
- SYNE1 | c.26280G>C p.G8760= (on ENST00000367255 / NM_182961.4; = p.G8712= on NM_033071.3) | Silent (SNP) | VAF 28/603 reads (5%) | called by muse, mutect2
- TEC | c.615G>A p.E205= | Silent (SNP) | VAF 9/238 reads (4%) | catalogued as rs1560385918; called by muse, mutect2
- XPC | c.1341C>T p.L447= | Silent (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- ZFP91 | c.288C>T p.P96= | Silent (SNP) | VAF 26/316 reads (8%) | catalogued as rs1419439095; called by muse, mutect2
- ZFR2 | c.972C>T p.C324= | Silent (SNP) | VAF 25/335 reads (7%) | catalogued as rs773842233, COSV99507699; called by muse, mutect2
- ZNF609 | c.915C>T p.P305= | Silent (SNP) | VAF 19/305 reads (6%) | catalogued as rs1170907582; called by muse, mutect2
- CHRNA4 | c.*2943G>A | 3'UTR (SNP) | VAF 8/164 reads (5%) | catalogued as rs1389563774; called by muse, mutect2
- GRB10 | c.846+58G>A | Intron (SNP) | VAF 23/269 reads (9%) | called by muse, mutect2
- ZNF716 | c.-8G>A | 5'UTR (SNP) | VAF 23/317 reads (7%) | catalogued as COSV70783789; called by muse, mutect2
